Somatic mutation profile of tumor specimen TCGA-66-2763-01A (aliquot TCGA-66-2763-01A-01W-0877-08) from TCGA case TCGA-66-2763, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.8 years (23,315 days).
Specimen TCGA-66-2763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2247b15f-8156-4ff8-96d1-d05ccefc323e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2763-11A (Solid Tissue Normal), aliquot TCGA-66-2763-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc451d41-45d7-4ee7-a7d6-e7db706e3cb2

The open-access MAF lists 407 somatic variants for this specimen: 314 protein-altering or splice-affecting, 87 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 271, Silent 87, Nonsense Mutation 25, Frame Shift Del 6, Splice Site 6, Intron 3, Frame Shift Ins 3, In Frame Ins 1, 3'UTR 1, Nonstop Mutation 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 66/156 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as COSV52707214; called by muse, mutect2, varscan2
- ABCA4 | c.4189T>G p.F1397V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs751233838, COSV64674203; called by muse, mutect2, varscan2
- ABCA5 | c.2484A>T p.E828D | Missense Mutation (SNP) | VAF 111/176 reads (63%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV67017206; called by muse, mutect2, varscan2
- ABCA6 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs1413978747, COSV52639708; called by muse, mutect2, varscan2
- ABCA9 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 177/306 reads (58%) | catalogued as COSV60626044; called by muse, mutect2, varscan2
- ABCB1 | c.2021G>C p.G674A | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55944671, COSV55953251; called by muse, mutect2, varscan2
- ABCB1 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV55953260; called by muse, mutect2, varscan2
- AC008397.2 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV53207445; called by muse, mutect2, varscan2
- ACSM2A | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54585563; called by muse, mutect2, varscan2
- ADAL | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 98/198 reads (49%) | catalogued as COSV67500655; called by muse, mutect2, varscan2
- ADAM21 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs192946121, COSV50796340; called by muse, mutect2, varscan2
- ADAMTS12 | c.4415G>T p.C1472F | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61264998; called by muse, mutect2, varscan2
- ADCY10 | c.2495G>A p.C832Y | Missense Mutation (SNP) | VAF 136/448 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV63241326; called by muse, mutect2, varscan2
- ADGRG6 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV51593810; called by muse, mutect2, varscan2
- ADGRG7 | c.1179G>A p.W393* | Nonsense Mutation (SNP) | VAF 18/205 reads (9%) | catalogued as COSV56297473; called by muse, mutect2
- ADRA1A | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52365385; called by muse, mutect2, varscan2
- AGTR2 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 321/439 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV64156534, COSV64157083; called by muse, mutect2, varscan2
- AGXT | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56754454; called by muse, mutect2, varscan2
- AHNAK2 | c.17054C>T p.A5685V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV60917756; called by muse, mutect2, varscan2
- AHRR | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs201569519, COSV57084895; called by muse, mutect2, varscan2
- ALMS1 | c.874C>G p.R292G | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV52511752; called by muse, mutect2, varscan2
- ALMS1 | c.7330C>G p.L2444V | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52511765; called by muse, mutect2, varscan2
- ANK2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); catalogued as COSV52165593; called by muse, mutect2, varscan2
- ARL4D | c.237dup p.Q80Afs*28 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | catalogued as rs758198899; called by pindel, varscan2
- ASIC5 | c.653C>G p.A218G | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV72232852; called by muse, mutect2, varscan2
- ASXL3 | c.3905G>T p.S1302I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV52468276; called by muse, mutect2, varscan2
- ATCAY | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755437219; called by mutect2, varscan2
- ATP10A | c.3658G>T p.G1220C | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV63518462; called by muse, mutect2, varscan2
- ATP2B1 | c.2332A>G p.K778E | Missense Mutation (SNP) | VAF 123/258 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV53808470; called by muse, mutect2, varscan2
- BBS4 | c.59A>T p.K20I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV51438310; called by muse, mutect2, varscan2
- BCORL1 | c.2366G>T p.R789L | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54390631, COSV54398067; called by muse, mutect2, varscan2
- BICC1 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV54064205; called by muse, mutect2, varscan2
- BICDL1 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 116/243 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV57493587; called by muse, mutect2, varscan2
- BVES | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58948288; called by muse, mutect2, varscan2
- C3 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV55581643; called by muse, mutect2, varscan2
- C6orf15 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as rs1394387039, COSV52538518; called by muse, mutect2
- C7 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV57475376, COSV57481219; called by muse, mutect2
- CACNA1F | c.2152T>A p.Y718N | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59904929; called by muse, mutect2, varscan2
- CALCR | c.599A>T p.H200L (on ENST00000649521 / NM_001164737.2; = p.H184L on NM_001742.4) | Missense Mutation (SNP) | VAF 123/359 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64008803; called by muse, mutect2, varscan2
- CALN1 | c.133T>A p.F45I (on ENST00000329008 / NM_001017440.3; = p.F87I on NM_031468.4) | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV61135953; called by muse, mutect2, varscan2
- CAPRIN1 | c.1560C>A p.F520L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58220230; called by muse, mutect2, varscan2
- CASD1 | c.1667A>T p.K556I | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51973023; called by muse, mutect2, varscan2
- CBLB | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 45/363 reads (12%) | catalogued as rs369966206; called by muse, mutect2, varscan2
- CCAR1 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV56266878; called by muse, mutect2, varscan2
- CCDC85A | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.121); catalogued as COSV68151792, COSV68156554; called by muse, mutect2, varscan2
- CCDC87 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs1267365194, COSV59579317; called by muse, mutect2, varscan2
- CD84 | c.499A>G p.N167D | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs139298884, COSV60868802; called by muse, mutect2, varscan2
- CDAN1 | c.2941A>G p.I981V | Missense Mutation (SNP) | VAF 216/678 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV62332419; called by muse, varscan2
- CDC42BPG | c.3598A>C p.K1200Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61347709; called by muse, mutect2
- CES1 | c.1257C>A p.D419E (on ENST00000361503 / NM_001025194.2; = p.D418E on NM_001266.5) | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs139540470, COSV62087397; called by muse, mutect2, varscan2
- CFAP44 | c.2142G>T p.M714I | Missense Mutation (SNP) | VAF 50/530 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55612169; called by muse, mutect2
- CFHR4 | c.1480G>T p.G494C (on ENST00000367416 / NM_001201551.2; = p.G248C on NM_006684.5) | Missense Mutation (SNP) | VAF 105/501 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52230136; called by muse, mutect2, varscan2
- CLDN10 | c.162C>G p.N54K | Missense Mutation (SNP) | VAF 270/387 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV65297815, COSV65299399; called by muse, mutect2, varscan2
- CLEC12A | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV58561425; called by muse, mutect2, varscan2
- CLEC17A | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60428160; called by muse, mutect2, varscan2
- CLN5 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV66284300; called by muse, mutect2, varscan2
- CLOCK | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 30/1006 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV59402386; called by muse, mutect2
- CLOCK | c.1709C>G p.S570* | Nonsense Mutation (SNP) | VAF 14/378 reads (4%) | catalogued as COSV59402394; called by muse, mutect2
- CMYA5 | c.11583G>T p.Q3861H | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69745709; called by muse, mutect2, varscan2
- CNTLN | c.2973G>T p.L991F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52081465; called by muse, mutect2, varscan2
- CNTN3 | c.1313G>T p.R438M | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV55173760; called by muse, mutect2, varscan2
- CNTNAP2 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV62192126; called by mutect2, varscan2
- CNTNAP2 | c.1664T>C p.I555T | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as rs780737228, COSV62192132, COSV62267449; called by muse, mutect2, varscan2
- CNTROB | c.2196G>C p.L732F | Missense Mutation (SNP) | VAF 216/508 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV66608374; called by muse, mutect2, varscan2
- COL11A1 | c.3365C>A p.P1122H | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62172782, COSV62185626; called by muse, mutect2, varscan2
- COL12A1 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); catalogued as COSV59397549; called by muse, mutect2, varscan2
- CPNE4 | c.1379C>A p.A460D | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70195155; called by muse, mutect2, varscan2
- CPSF1 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52779323; called by muse, mutect2, varscan2
- CRB1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.688); catalogued as COSV66342336; called by muse, mutect2, varscan2
- CRYBG2 | c.3511G>T p.V1171L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV57486552; called by muse, mutect2, varscan2
- CSMD3 | c.10228A>T p.S3410C (on ENST00000297405 / NM_001363185.1; = p.S3241C on NM_052900.3) | Missense Mutation (SNP) | VAF 123/263 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV52202283, COSV52320309; called by muse, mutect2, varscan2
- CST11 | c.72C>A p.Y24* | Nonsense Mutation (SNP) | VAF 62/202 reads (31%) | catalogued as COSV63140138; called by muse, mutect2, varscan2
- CWF19L2 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56513760; called by muse, mutect2, varscan2
- CYP1A1 | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as COSV65697421; called by muse, mutect2, varscan2
- DCSTAMP | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 183/890 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV52577317, COSV52578105; called by muse, mutect2, varscan2
- DDIAS | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 110/885 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61272364; called by muse, mutect2, varscan2
- DENND2A | c.356del p.G119Dfs*10 | Frame Shift Del (DEL) | VAF 125/437 reads (29%) | catalogued as COSV52052672; called by mutect2, pindel, varscan2
- DENND4B | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57843382; called by mutect2, varscan2
- DIO3 | c.874T>A p.Y292N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63773841; called by muse, mutect2, varscan2
- DMD | c.10666G>T p.A3556S | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV58916890; called by muse, mutect2, varscan2
- DNAJB1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV54317153; called by muse, mutect2, varscan2
- EFCAB6 | c.4225C>A p.H1409N | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV53064957; called by muse, mutect2, varscan2
- ENTHD1 | c.968C>A p.A323E | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV57321098; called by muse, mutect2, varscan2
- EXO5 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV56415858, COSV99591198; called by muse, mutect2, varscan2
- EXOSC10 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV58665820, COSV58668384; called by muse, mutect2, varscan2
- EYA4 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 138/231 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs752023028, COSV62053553, COSV62060270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA4 | c.1613C>G p.S538C (on ENST00000531901 / NM_001301013.1; = p.S532C on NM_004100.5) | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV100766215, COSV62053567; called by muse, mutect2, varscan2
- FAM13A | c.1721G>C p.W574S | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52004091, COSV52015190; called by muse, mutect2, varscan2
- FAM149A | c.2249-1G>C p.X750_splice (on ENST00000356371 / NM_001367768.2; = p.X459_splice on NM_015398.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/68 reads (28%) | catalogued as rs756989427, COSV57027904; called by muse, mutect2, varscan2
- FAM234B | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1481988179, COSV52195043; called by muse, mutect2, varscan2
- FAM50A | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV50131468; called by muse, mutect2, varscan2
- FAT4 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV67888776; called by muse, mutect2, varscan2
- FBXO22 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs141220458, COSV57617752; called by muse, mutect2, varscan2
- FLG2 | c.3022C>A p.Q1008K | Missense Mutation (SNP) | VAF 407/1248 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV66169311; called by muse, mutect2, varscan2
- FREM1 | c.3646C>T p.Q1216* | Nonsense Mutation (SNP) | VAF 114/246 reads (46%) | catalogued as COSV101085038, COSV66524892; called by muse, mutect2
- FRYL | c.6554A>G p.Y2185C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51949584; called by muse, mutect2
- FTMT | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58420507; called by muse, mutect2, varscan2
- GABRR1 | c.1073C>A p.S358* | Nonsense Mutation (SNP) | VAF 116/230 reads (50%) | catalogued as COSV65619614, COSV99055045; called by muse, mutect2, varscan2
- GHRHR | c.1208G>C p.R403T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs767279880, COSV58196810; called by muse, mutect2, varscan2
- GIMAP1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV56188443; called by muse, mutect2, varscan2
- GP5 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs759376535, COSV59878665; called by muse, mutect2, varscan2
- GPC3 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 54/204 reads (26%) | catalogued as COSV63665417; called by muse, varscan2
- GRHL3 | c.451G>T p.G151C (on ENST00000350501 / NM_198174.3; = p.G156C on NM_021180.3) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV52567517; called by muse, mutect2, varscan2
- GRIA2 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52389055, COSV52392928; called by muse, mutect2, varscan2
- GRIA2 | c.2078C>G p.T693S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52392981; called by muse, mutect2, varscan2
- GRK5 | c.1564A>G p.K522E | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV64866568; called by muse, mutect2, varscan2
- GRPR | c.959T>A p.F320Y | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66669591; called by muse, mutect2, varscan2
- GUCY1A1 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56652363; called by muse, mutect2, varscan2
- H2AC20 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV58612190, COSV58612981; called by muse, mutect2, varscan2
- H4C4 | c.233A>T p.K78I | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV61591191; called by muse, mutect2, varscan2
- HELQ | c.2815T>G p.F939V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV55025621, COSV99788186; called by muse, mutect2, varscan2
- HEXA | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD123438, COSV51506910; called by muse, mutect2, varscan2
- HNMT | c.464T>A p.L155Q | Missense Mutation (SNP) | VAF 267/549 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54508192; called by muse, mutect2, varscan2
- HOXA1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029958; called by muse, mutect2, varscan2
- HOXD9 | c.215C>G p.S72W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50892160; called by mutect2, varscan2
- HSPA8 | c.1740G>T p.W580C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57084260; called by muse, mutect2, varscan2
- HUWE1 | c.12031G>T p.G4011W | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53348438; called by muse, mutect2, varscan2
- IFIT1B | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65663484; called by muse, mutect2, varscan2
- IGHV1-45 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 82/348 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs782800612; called by muse, mutect2, varscan2
- INMT | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV50001617; called by muse, mutect2, varscan2
- INSRR | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV63874324; called by muse, mutect2, varscan2
- INTS8 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.927); catalogued as COSV58250976; called by muse, mutect2, varscan2
- ITIH6 | c.2080C>A p.P694T | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV54489950; called by muse, mutect2
- ITPRID1 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 19/355 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60075965; called by muse, mutect2
- ITPRIPL1 | c.468C>A p.Y156* (on ENST00000439118 / NM_001008949.3; = p.Y164* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV63153730; called by muse, mutect2
- JMJD1C | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as COSV67862721; called by muse, mutect2, varscan2
- KBTBD3 | c.1700A>C p.D567A | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.999); catalogued as COSV73241458; called by muse, mutect2, varscan2
- KCNN2 | c.1518G>T p.R506S (on ENST00000264773; = p.R718S on NM_021614.4) | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV53290201; called by muse, mutect2, varscan2
- KCTD14 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773238436, COSV62001552; called by muse, mutect2, varscan2
- KIAA1217 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs569802646, COSV56817736; called by muse, mutect2, varscan2
- KIAA1549 | c.5444G>T p.G1815V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1056618266, COSV54316643; called by muse, mutect2, varscan2
- KIF14 | c.3659C>T p.S1220L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV66262101; called by muse, mutect2, varscan2
- KIF21A | c.2617G>T p.A873S (on ENST00000361418 / NM_001378440.1; = p.A860S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746913383, COSV62772539; called by muse, mutect2, varscan2
- KIF26B | c.6069C>A p.H2023Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as COSV63643380; called by muse, mutect2
- KLHL28 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV61888393; called by muse, mutect2, varscan2
- KLHL9 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.602); catalogued as COSV62921742; called by muse, mutect2, varscan2
- KRTAP10-8 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 104/193 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV58166491; called by muse, mutect2, varscan2
- LCP2 | c.1266G>C p.W422C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50452340; called by muse, mutect2, varscan2
- LIPF | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 177/327 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1397424838, COSV53284432; called by muse, mutect2, varscan2
- LRP1B | c.11834G>T p.G3945V | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV67196683, COSV67230129; called by muse, mutect2, varscan2
- LRRC37A3 | c.3761G>C p.G1254A | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58535613; called by muse, mutect2, varscan2
- LYSMD1 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 170/567 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64423365; called by muse, mutect2, varscan2
- MAP1B | c.4648G>T p.A1550S | Missense Mutation (SNP) | VAF 291/553 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); catalogued as COSV57100457; called by muse, mutect2, varscan2
- MAP3K13 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as rs930308945; called by muse, mutect2
- MCF2L2 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as COSV61054899; called by muse, mutect2, varscan2
- MCOLN2 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 250/495 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs762235549, COSV52296413; called by muse, mutect2, varscan2
- MS4A14 | c.1939del p.Q647Kfs*31 | Frame Shift Del (DEL) | VAF 48/160 reads (30%) | catalogued as COSV55735349; called by mutect2, pindel, varscan2
- MTR | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs372611712; called by muse, mutect2, varscan2
- MUC16 | c.18767C>A p.T6256N | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV67471814; called by muse, mutect2, varscan2
- MYBBP1A | c.3562G>T p.D1188Y | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV54598491; called by muse, mutect2, varscan2
- MYH6 | c.3841A>T p.K1281* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV62451521; called by muse, mutect2, varscan2
- MYO18A | c.3800G>C p.R1267P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV62867799, COSV62870047; called by muse, mutect2, varscan2
- MYO18B | c.5061G>T p.K1687N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59136684, COSV59145707; called by muse, mutect2, varscan2
- MYO18B | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59136690; called by muse, mutect2, varscan2
- MYO1F | c.2053C>A p.L685M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57795994; called by muse, mutect2, varscan2
- MYO3B | c.1265G>T p.C422F | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100508843, COSV58705520; called by muse, varscan2
- NAV3 | c.3797C>A p.T1266N | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57084949; called by muse, mutect2, varscan2
- NAV3 | c.4631-1G>T p.X1544_splice | Splice Site (SNP) | VAF 31/66 reads (47%) | catalogued as COSV57084959; called by muse, mutect2, varscan2
- NCAM2 | c.1705G>C p.V569L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as rs761349725, COSV53079918; called by muse, mutect2, varscan2
- NDST2 | c.2590C>T p.R864W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766202073, COSV55214921; called by muse, mutect2, varscan2
- NEBL | c.2761+2T>C p.X921_splice | Splice Site (SNP) | VAF 58/256 reads (23%) | catalogued as rs139887121, COSV65803429; called by muse, mutect2, varscan2
- NKTR | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs746276547, COSV51772431; called by muse, mutect2, varscan2
- NLRP11 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV64087407; called by muse, mutect2, varscan2
- NLRP12 | c.3137G>T p.R1046M | Missense Mutation (SNP) | VAF 145/286 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV60748857; called by muse, mutect2, varscan2
- NLRP14 | c.2561T>A p.V854D | Missense Mutation (SNP) | VAF 109/231 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.259); catalogued as COSV55067897; called by muse, mutect2, varscan2
- NNT | c.2851C>T p.L951F | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52925747; called by muse, mutect2
- NOL4L | c.70A>T p.R24W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV58170144; called by muse, mutect2
- NOL8 | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 63/109 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV62635699; called by muse, mutect2, varscan2
- NOTCH4 | c.1499T>C p.L500P | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV66681289; called by muse, mutect2, varscan2
- NPAT | c.3603A>G p.I1201M | Missense Mutation (SNP) | VAF 174/573 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53718569; called by muse, mutect2, varscan2
- NR4A1 | c.884T>A p.V295E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54483221; called by muse, mutect2, varscan2
- NRK | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 90/126 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV54598408; called by muse, mutect2, varscan2
- NRXN1 | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 84/190 reads (44%) | catalogued as COSV58459244, COSV58493099; called by muse, mutect2, varscan2
- NUP210L | c.4702A>T p.T1568S | Missense Mutation (SNP) | VAF 173/454 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55149400; called by muse, mutect2, varscan2
- NXPE1 | c.834G>T p.R278S (on ENST00000424269; = p.R136S on NM_152315.5) | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV99320705; called by mutect2, varscan2
- OR10R2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63768927; called by muse, mutect2, varscan2
- OR14C36 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV58601560, COSV58602691; called by muse, mutect2, varscan2
- OR2J2 | c.217T>C p.C73R | Missense Mutation (SNP) | VAF 117/442 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV65848078; called by muse, mutect2, varscan2
- OR2T4 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.049); catalogued as COSV63544177; called by muse, mutect2, varscan2
- OR2T5 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 76/523 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV63540621; called by muse, mutect2, varscan2
- OR4C11 | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 120/336 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV56353063, COSV56353716; called by muse, mutect2, varscan2
- OR4C11 | c.97T>G p.Y33D | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56353725; called by muse, mutect2, varscan2
- OR52B4 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs780185004, COSV68769057; called by muse, mutect2, varscan2
- OTUD4 | c.911A>T p.D304V (on ENST00000447906 / NM_001366057.1; = p.D239V on NM_001102653.1) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1269288550, COSV71381938, COSV71382265; called by muse, mutect2, varscan2
- OXSR1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 128/242 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs755028275, COSV61259019; called by muse, mutect2, varscan2
- PACRGL | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 93/375 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV54843034; called by muse, mutect2, varscan2
- PALD1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 48/268 reads (18%) | catalogued as COSV54974576; called by muse, varscan2
- PAPPA2 | c.1558C>G p.R520G | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV62776814, COSV62779600; called by muse, mutect2, varscan2
- PBX1 | c.1109A>T p.Q370L | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs747269460, COSV63344545; called by muse, mutect2, varscan2
- PCDHGB4 | c.2249A>T p.Y750F | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV53963412; called by muse, mutect2, varscan2
- PCMTD1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 87/149 reads (58%) | catalogued as COSV62122925; called by muse, mutect2, varscan2
- PDZD2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56860518; called by muse, mutect2, varscan2
- PELI2 | c.309+1G>T p.X103_splice | Splice Site (SNP) | VAF 40/105 reads (38%) | catalogued as COSV50711767, COSV99953068; called by muse, mutect2, varscan2
- PIWIL3 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV59996070; called by muse, mutect2, varscan2
- PKHD1 | c.11686C>A p.P3896T | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64391915; called by muse, mutect2, varscan2
- PLD4 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66915281; called by muse, mutect2, varscan2
- PLEKHO2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs776326536, COSV60262213; called by muse, mutect2, varscan2
- PNMA8A | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV58137379; called by muse, varscan2
- POLD2 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV56258559; called by muse, mutect2, varscan2
- POLK | c.2504A>G p.Q835R | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54035926; called by muse, mutect2, varscan2
- POLR3B | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57276226, COSV57279895; called by muse, mutect2, varscan2
- PON1 | c.839T>A p.L280H | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55932339; called by muse, mutect2, varscan2
- PON1 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV55932351; called by muse, mutect2, varscan2
- POTEE | c.2680A>C p.T894P | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV58233083; called by muse, mutect2, varscan2
- PREX2 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55775722; called by muse, mutect2, varscan2
- PRKCB | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 186/491 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV57776596, COSV57783158; called by muse, mutect2, varscan2
- PRKN | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV58232341; called by muse, mutect2, varscan2
- PRR23B | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.583); catalogued as COSV61494052; called by muse, mutect2, varscan2
- PSKH1 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52123727, COSV99344542; called by muse, mutect2, varscan2
- RAB40A | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 193/249 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58491402; called by muse, mutect2, varscan2
- RBM3 | c.31G>T p.G11* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV63202604; called by muse, mutect2, varscan2
- RCAN1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.932); catalogued as COSV58250262; called by muse, mutect2, varscan2
- RELN | c.4121T>A p.V1374D | Missense Mutation (SNP) | VAF 289/743 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.945); catalogued as COSV59007466; called by muse, mutect2, varscan2
- RGS8 | c.482G>T p.R161M (on ENST00000367556 / NM_001369564.2; = p.R179M on NM_033345.3) | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51116999; called by muse, mutect2, varscan2
- RINT1 | c.2345A>T p.N782I | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57558915; called by muse, mutect2, varscan2
- ROBO2 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59915004, COSV59917995; called by muse, mutect2, varscan2
- ROR2 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65219835; called by muse, mutect2, varscan2
- RP1 | c.5147G>T p.G1716V | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV55118507; called by muse, mutect2, varscan2
- RUNX1T1 | c.1372C>T p.R458C (on ENST00000265814 / NM_001198628.1; = p.R431C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1381105316, COSV56138759; called by muse, mutect2, varscan2
- S1PR1 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 119/199 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513445; called by muse, mutect2, varscan2
- SART1 | c.1661A>T p.N554I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56712030; called by muse, mutect2, varscan2
- SCARF1 | c.2333G>T p.R778L | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV53959129, COSV53960134; called by muse, mutect2, varscan2
- SCML2 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 157/674 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52621873; called by muse, mutect2, varscan2
- SCN1A | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57662076, COSV57672659; called by muse, mutect2, varscan2
- SCN7A | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV69270645; called by muse, mutect2, varscan2
- SENP1 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV50291237; called by mutect2, varscan2
- SF1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs763865200, COSV57114449; called by muse, mutect2, varscan2
- SGPP1 | c.775-1G>A p.X259_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99905915; called by muse, mutect2, varscan2
- SIGLEC12 | c.1692G>T p.Q564H (on ENST00000291707 / NM_053003.4; = p.Q446H on NM_033329.2) | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52462138; called by muse, mutect2, varscan2
- SLC22A12 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60572478; called by muse, mutect2, varscan2
- SLC24A4 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV54114245; called by muse, mutect2, varscan2
- SLC35F2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 114/350 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.204); catalogued as COSV56183616; called by muse, mutect2, varscan2
- SLC5A11 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 36/695 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs200088797; called by muse, mutect2
- SLC6A14 | c.1038T>A p.D346E | Missense Mutation (SNP) | VAF 325/512 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64147334; called by muse, mutect2, varscan2
- SNX24 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV54452093; called by muse, mutect2, varscan2
- SORCS3 | c.1351C>A p.Q451K | Missense Mutation (SNP) | VAF 92/168 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV63812621; called by muse, mutect2, varscan2
- SPAM1 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs748725260, COSV56144485, COSV56146996; called by muse, mutect2, varscan2
- SPATA19 | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54483595; called by muse, mutect2
- SPATA31D1 | c.4363C>G p.Q1455E | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.702); catalogued as COSV61196738; called by muse, mutect2, varscan2
- SPEF2 | c.3064-1G>T p.X1022_splice | Splice Site (SNP) | VAF 25/110 reads (23%) | catalogued as COSV61548962; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59131752; called by muse, mutect2, varscan2
- STYK1 | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 367/1332 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV50013456; called by muse, mutect2, varscan2
- SYCP2L | c.171A>T p.K57N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51653966; called by muse, mutect2, varscan2
- SYT11 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 142/464 reads (31%) | catalogued as COSV64174084, COSV64174744; called by muse, mutect2, varscan2
- SYTL2 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV60359839; called by muse, mutect2, varscan2
- TAAR5 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as rs1321627353, COSV57799186; called by muse, varscan2
- TBC1D25 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.601); catalogued as COSV65123891; called by muse, mutect2, varscan2
- TET1 | c.1551A>C p.L517F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65385448; called by muse, mutect2, varscan2
- TET1 | c.6358G>T p.V2120L | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV65381772, COSV65385455; called by muse, mutect2, varscan2
- THADA | c.4433A>T p.Q1478L | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV57685412; called by muse, mutect2, varscan2
- THEMIS | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.162); catalogued as COSV64071660; called by muse, mutect2, varscan2
- TIPARP | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 29/137 reads (21%) | catalogued as COSV55814415; called by muse, mutect2, varscan2
- TLL2 | c.1759G>T p.G587W | Missense Mutation (SNP) | VAF 116/180 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63570541, COSV63572986; called by muse, mutect2, varscan2
- TMEM39A | c.1416A>T p.L472F | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59900616; called by muse, mutect2, varscan2
- TMIGD1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61028699; called by muse, mutect2, varscan2
- TMPRSS7 | c.1447C>T p.P483S (on ENST00000452346; = p.P357S on NM_001042575.2) | Missense Mutation (SNP) | VAF 46/407 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757002153, COSV69981039; called by muse, mutect2, varscan2
- TNN | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 196/582 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs749585837, COSV53427335; called by mutect2, varscan2
- TRA2B | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52025568; called by muse, mutect2, varscan2
- TREML4 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58385315; called by muse, mutect2, varscan2
- TRIM42 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53883685; called by muse, mutect2, varscan2
- TRIM72 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV59068159; called by mutect2, varscan2
- TRMT2B | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 421/525 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV58619792; called by muse, mutect2, varscan2
- TTN | c.33407del p.P11136Lfs*29 (on ENST00000591111; = p.P10209Lfs*29 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/40 reads (60%) | catalogued as COSV100596568; called by mutect2, pindel, varscan2
- TTPA | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.268); catalogued as COSV52646893; called by muse, mutect2, varscan2
- TULP1 | c.1081del p.R361Efs*10 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as CM140477, COSV57693341; called by mutect2, pindel, varscan2
- TXLNG | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 51/255 reads (20%) | catalogued as COSV58113055; called by muse, mutect2, varscan2
- U2SURP | c.3089G>C p.*1030Sext*73 | Nonstop Mutation (SNP) | VAF 44/78 reads (56%) | catalogued as COSV67531362; called by muse, mutect2, varscan2
- UGT2A3 | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as COSV52360463; called by muse, mutect2, varscan2
- UNC5D | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV54800873; called by muse, mutect2
- USP11 | c.1533G>T p.Q511H (on ENST00000218348; = p.Q468H on NM_001371072.1) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54474033; called by muse, mutect2, varscan2
- USP24 | c.5185G>A p.D1729N | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV53769421; called by muse, mutect2, varscan2
- USP9X | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV61069973; called by mutect2, varscan2
- WDR26 | c.1325A>T p.Q442L (on ENST00000414423 / NM_001379403.1; = p.Q342L on NM_025160.7) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV54356126; called by muse, mutect2, varscan2
- WDR33 | c.3274G>T p.E1092* | Nonsense Mutation (SNP) | VAF 64/248 reads (26%) | catalogued as COSV59249947, COSV59252702; called by muse, mutect2, varscan2
- WDR72 | c.1995T>G p.F665L | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.556); catalogued as COSV64748154; called by muse, mutect2, varscan2
- WNK3 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100671707; called by muse, mutect2, varscan2
- WNT10B | c.1069C>G p.R357G | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV56405562; called by muse, mutect2, varscan2
- XKR7 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs984731810, COSV73813198; called by mutect2, varscan2
- YTHDC2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV50742354; called by mutect2, varscan2
- ZBTB46 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55510911; called by muse, mutect2, varscan2
- ZFAND6 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1394761608, COSV55712165; called by muse, mutect2, varscan2
- ZFP64 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53800149; called by muse, mutect2, varscan2
- ZIC1 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51554248; called by muse, mutect2, varscan2
- ZNF318 | c.4234G>A p.G1412R | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58933316; called by muse, mutect2
- ZNF320 | c.1299G>T p.R433S | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV67088281; called by muse, mutect2, varscan2
- ZNF324B | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60742154; called by muse, mutect2, varscan2
- ZNF480 | c.1370G>T p.C457F | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57996587; called by muse, mutect2, varscan2
- ZNF527 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 134/439 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV62231158; called by muse, mutect2, varscan2
- ZNF583 | c.82A>T p.R28W | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52402912; called by muse, mutect2, varscan2
- ZNF665 | c.1502G>T p.G501V (on ENST00000600412; = p.G566V on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV67215556; called by muse, mutect2, varscan2
- ZNF783 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV65185614; called by muse, varscan2
- ZNF804B | c.988C>G p.H330D | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV60831186, COSV60832295; called by muse, mutect2, varscan2
- AJAP1 | c.85_86insAATGGACTA p.L28_I29insKWT | In Frame Ins (INS) | VAF 13/94 reads (14%) | called by muse*, mutect2, varscan2*
- ARHGEF5 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 95/688 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ATOH1 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CDH19 | c.411dup p.V138Sfs*6 | Frame Shift Ins (INS) | VAF 40/91 reads (44%) | called by mutect2, varscan2
- FAM117A | c.331del p.A111Pfs*20 | Frame Shift Del (DEL) | VAF 111/183 reads (61%) | called by mutect2, pindel, varscan2
- IGHE | c.677_682del p.P226_D228delinsH | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- IGHG3 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 105/212 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV2-18 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 332/906 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- IRAK3 | c.1157T>G p.L386R | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KMT2D | c.2760dup p.G921Wfs*48 | Frame Shift Ins (INS) | VAF 50/172 reads (29%) | called by mutect2, pindel, varscan2
- MCOLN1 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAB29 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 165/1252 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by mutect2, varscan2
- RASGRP1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 15/449 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.142); called by muse, mutect2
- RYR3 | c.6985G>A p.V2329I (on ENST00000389232; = p.V2330I on NM_001036.6) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- TANC2 | c.5863G>C p.V1955L | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); called by muse, mutect2
- TRAV22 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TRAV29DV5 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- TRAV29DV5 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRDV2 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 149/378 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TTN | c.82935del p.A27646Pfs*114 (on ENST00000591111; = p.A20222Pfs*114 on NM_003319.4) | Frame Shift Del (DEL) | VAF 72/173 reads (42%) | called by mutect2, pindel, varscan2
- ABCA1 | c.5409G>T p.L1803= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV66066929; called by muse, mutect2, varscan2
- ADAMTS9 | c.2118A>T p.I706= | Silent (SNP) | VAF 80/179 reads (45%) | catalogued as COSV55782831; called by muse, mutect2, varscan2
- ADRA1A | c.363C>A p.S121= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV52365324; called by muse, mutect2, varscan2
- AKAP13 | c.1170C>T p.D390= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as COSV63460645; called by muse, mutect2
- AOC1 | c.996C>G p.S332= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100710854; called by mutect2, varscan2
- APMAP | c.633G>A p.K211= | Silent (SNP) | VAF 103/335 reads (31%) | catalogued as COSV54174340; called by muse, mutect2, varscan2
- ARHGEF15 | c.1785C>A p.I595= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV62724633, COSV62725454; called by muse, mutect2, varscan2
- BDH1 | c.447G>T p.T149= | Silent (SNP) | VAF 172/417 reads (41%) | catalogued as rs374123564; called by muse, mutect2
- C10orf90 | c.1893G>C p.L631= | Silent (SNP) | VAF 67/107 reads (63%) | catalogued as COSV52949081, COSV52956733; called by muse, mutect2, varscan2
- CACNA1F | c.4992G>T p.T1664= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV59904924; called by muse, mutect2, varscan2
- CAPN6 | c.1719C>T p.T573= | Silent (SNP) | VAF 66/1172 reads (6%) | catalogued as rs751638806, COSV60695334; called by muse, mutect2
- CARMIL1 | c.537A>G p.Q179= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as rs1405218344, COSV61518702; called by muse, mutect2, varscan2
- CASK | c.2550T>C p.F850= (on ENST00000378163 / NM_001367721.1; = p.F845= on NM_003688.3) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59367953; called by muse, mutect2, varscan2
- CEP170 | c.3255A>G p.S1085= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as rs1558468396, COSV60509975; called by muse, mutect2, varscan2
- CHRD | c.2766G>C p.S922= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs549612778; called by mutect2, varscan2
- CNTN3 | c.1407G>C p.V469= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV55173748; called by muse, mutect2, varscan2
- COL18A1 | c.5229C>G p.L1743= (on ENST00000359759 / NM_130444.3; = p.L1508= on NM_030582.4) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1171902353, COSV60589555; called by muse, mutect2
- CSMD3 | c.8634T>A p.P2878= (on ENST00000297405 / NM_001363185.1; = p.P2709= on NM_052900.3) | Silent (SNP) | VAF 46/210 reads (22%) | catalogued as COSV52202300; called by muse, mutect2, varscan2
- CTSC | c.780A>C p.S260= | Silent (SNP) | VAF 58/185 reads (31%) | catalogued as COSV57058305; called by muse, mutect2, varscan2
- DGKK | c.3540C>A p.A1180= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs1023803651, COSV65707839; called by muse, mutect2, varscan2
- DIO2 | c.426C>A p.A142= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV70445196, COSV70445273; called by muse, mutect2, varscan2
- DNAH9 | c.6570C>T p.L2190= | Silent (SNP) | VAF 52/201 reads (26%) | called by muse, varscan2
- DQX1 | c.1587G>C p.L529= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as COSV52046186; called by muse, mutect2, varscan2
- DSC2 | c.912C>A p.I304= | Silent (SNP) | VAF 161/424 reads (38%) | catalogued as COSV51865657, COSV99199896; called by muse, mutect2, varscan2
- EGFR | c.1707C>T p.I569= | Silent (SNP) | VAF 95/430 reads (22%) | catalogued as COSV51807289; called by muse, mutect2, varscan2
- EHHADH | c.213A>G p.T71= | Silent (SNP) | VAF 97/172 reads (56%) | catalogued as COSV51630708; called by muse, mutect2, varscan2
- FAM126A | c.1479C>T p.Y493= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as rs759045816, COSV69472027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM78B | c.333C>T p.S111= | Silent (SNP) | VAF 50/403 reads (12%) | catalogued as COSV57978107; called by muse, mutect2, varscan2
- FCER1A | c.486C>T p.S162= | Silent (SNP) | VAF 115/459 reads (25%) | catalogued as COSV63667046; called by muse, mutect2, varscan2
- FLCN | c.345C>G p.P115= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV53259909; called by muse, mutect2, varscan2
- FLYWCH1 | c.960A>G p.G320= (on ENST00000253928 / NM_001308068.2; = p.G319= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV54146656; called by muse, mutect2
- FPGT-TNNI3K | c.138T>C p.R46= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV63041908; called by muse, mutect2, varscan2
- FSCB | c.30A>G p.V10= | Silent (SNP) | VAF 236/576 reads (41%) | catalogued as COSV61218368; called by muse, mutect2, varscan2
- FUT8 | c.531T>A p.G177= (on ENST00000360689 / NM_001371534.1; = p.G14= on NM_004480.4) | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as COSV61285586; called by muse, mutect2, varscan2
- GALC | c.429T>C p.N143= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV54326249; called by muse, mutect2, varscan2
- GDI2 | c.259C>T p.L87= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV66335026; called by muse, mutect2, varscan2
- GNL3L | c.510G>T p.L170= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV60576685; called by muse, mutect2, varscan2
- GPR22 | c.990T>A p.S330= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV51753380; called by muse, mutect2, varscan2
- GRB10 | c.1239G>A p.R413= (on ENST00000398812; = p.R367= on NM_001001549.3) | Silent (SNP) | VAF 148/441 reads (34%) | catalogued as COSV60011365; called by muse, mutect2, varscan2
- GRIA2 | c.1779G>T p.G593= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV52390550, COSV52392955; called by muse, mutect2, varscan2
- GTPBP3 | c.693G>T p.V231= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV50180145; called by muse, mutect2, varscan2
- HLA-DQA1 | c.219G>A p.E73= | Silent (SNP) | VAF 56/177 reads (32%) | catalogued as COSV58239533; called by muse, mutect2, varscan2
- ITGAV | c.1797T>A p.A599= | Silent (SNP) | VAF 104/220 reads (47%) | catalogued as COSV53713730; called by muse, mutect2, varscan2
- KLK13 | c.276G>T p.G92= | Silent (SNP) | VAF 96/196 reads (49%) | catalogued as COSV50067132; called by mutect2, varscan2
- LCT | c.1086C>A p.I362= | Silent (SNP) | VAF 73/136 reads (54%) | catalogued as COSV51550983; called by muse, mutect2, varscan2
- LRRTM1 | c.1170G>T p.S390= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs200884012, COSV54439806, COSV54442685; called by muse, mutect2, varscan2
- MS4A8 | c.630C>A p.V210= | Silent (SNP) | VAF 173/464 reads (37%) | catalogued as COSV55754647; called by muse, mutect2, varscan2
- MUC16 | c.29349T>A p.S9783= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV67471806; called by muse, mutect2, varscan2
- MYO18B | c.6030G>A p.A2010= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs748527777, COSV59136698; called by muse, mutect2, varscan2
- NLRP2 | c.829C>T p.L277= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV54754584; called by muse, mutect2, varscan2
- OR2L3 | c.81C>T p.F27= | Silent (SNP) | VAF 342/1026 reads (33%) | catalogued as rs1263475318, COSV63455372; called by muse, mutect2, varscan2
- OR2M7 | c.237C>A p.P79= | Silent (SNP) | VAF 366/973 reads (38%) | catalogued as COSV58739371; called by muse, mutect2, varscan2
- OR51L1 | c.108A>G p.A36= | Silent (SNP) | VAF 30/446 reads (7%) | catalogued as rs778071155, COSV58624921; called by muse, mutect2
- OR51S1 | c.933C>G p.L311= | Silent (SNP) | VAF 89/206 reads (43%) | catalogued as COSV59058746; called by muse, mutect2, varscan2
- OSBPL3 | c.2031T>C p.F677= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs1176015936, COSV57657554; called by muse, mutect2, varscan2
- PALD1 | c.492G>T p.R164= | Silent (SNP) | VAF 50/267 reads (19%) | catalogued as COSV54974564; called by muse, varscan2
- PCDH1 | c.402G>A p.L134= | Silent (SNP) | VAF 71/124 reads (57%) | catalogued as rs746401175, COSV54614760; called by muse, mutect2, varscan2
- PCDHGB2 | c.2137C>T p.L713= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV53963402; called by muse, mutect2, varscan2
- PGBD2 | c.1150C>T p.L384= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV61400367; called by muse, mutect2, varscan2
- PIWIL2 | c.234G>A p.L78= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV63251998; called by muse, mutect2, varscan2
- PKHD1 | c.3621C>A p.S1207= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV61879722; called by muse, mutect2, varscan2
- PLXNA2 | c.297C>A p.I99= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV65441427; called by muse, mutect2, varscan2
- POLR1C | c.645C>T p.V215= | Silent (SNP) | VAF 12/213 reads (6%) | catalogued as rs377211362; called by muse, mutect2
- POP1 | c.1302G>C p.L434= | Silent (SNP) | VAF 152/828 reads (18%) | catalogued as COSV62893054; called by muse, varscan2
- PRSS12 | c.1677A>G p.K559= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV56606933; called by muse, mutect2, varscan2
- PTCD1 | c.1530C>G p.L510= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV52864248; called by muse, mutect2, varscan2
- PTGDR | c.663C>T p.A221= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV60094178; called by muse, mutect2, varscan2
- PXDNL | c.3411G>A p.S1137= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as COSV100686303, COSV62489353; called by muse, mutect2, varscan2
- RINL | c.855C>T p.I285= (on ENST00000591812 / NM_001195833.2; = p.I171= on NM_198445.4) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61574916; called by muse, mutect2
- SETDB1 | c.99G>T p.L33= | Silent (SNP) | VAF 175/522 reads (34%) | catalogued as COSV54984525; called by muse, mutect2, varscan2
- SIGLECL1 | c.135C>A p.P45= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as COSV57063214, COSV57064647; called by muse, mutect2, varscan2
- SLC5A11 | c.639A>T p.I213= | Silent (SNP) | VAF 288/865 reads (33%) | catalogued as COSV61741987; called by muse, mutect2, varscan2
- SLCO5A1 | c.1110A>G p.K370= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- SLITRK1 | c.1446G>T p.L482= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs1228290125, COSV65676102; called by muse, mutect2, varscan2
- TAS2R1 | c.696C>A p.S232= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as COSV66778783; called by muse, mutect2, varscan2
- TATDN3 | c.123A>C p.A41= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV65325383; called by muse, mutect2, varscan2
- TBC1D22B | c.1278G>A p.L426= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as COSV65142866; called by muse, mutect2, varscan2
- TMEM131L | c.828C>T p.N276= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV53645413; called by muse, mutect2, varscan2
- TPO | c.1695T>C p.F565= | Silent (SNP) | VAF 74/138 reads (54%) | catalogued as rs756738202, COSV61103337; called by muse, mutect2, varscan2
- TRAF2 | c.414G>T p.A138= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV56038417; called by muse, mutect2, varscan2
- TRIM47 | c.1557C>T p.S519= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV54668572; called by muse, mutect2, varscan2
- TRIO | c.1203C>T p.I401= | Silent (SNP) | VAF 695/993 reads (70%) | called by muse, varscan2
- UNC13C | c.4638A>T p.V1546= | Silent (SNP) | VAF 74/319 reads (23%) | catalogued as COSV52881912; called by muse, mutect2, varscan2
- WNK3 | c.1500T>A p.A500= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as COSV63614470; called by muse, mutect2, varscan2
- ZCWPW2 | c.312A>T p.V104= | Silent (SNP) | VAF 118/236 reads (50%) | catalogued as COSV67499353; called by muse, mutect2, varscan2
- ZFYVE26 | c.5769G>T p.R1923= | Silent (SNP) | VAF 96/231 reads (42%) | catalogued as COSV61329451; called by muse, mutect2, varscan2
- ZIC1 | c.411C>A p.A137= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV51552643, COSV51554266; called by muse, mutect2, varscan2
- ANK1 | c.5619+263G>T | Intron (SNP) | VAF 43/240 reads (18%) | catalogued as COSV99226045; called by muse, mutect2, varscan2
- COL11A1 | c.898-277del | Intron (DEL) | VAF 28/72 reads (39%) | catalogued as COSV62196478; called by mutect2, pindel, varscan2
- MFRP | chr11:119345849 del G | 5'Flank (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- NOP58 | c.122+1298_122+1300del | Intron (DEL) | VAF 10/44 reads (23%) | called by pindel, varscan2
- SLC22A17 | n.1019C>T | RNA (SNP) | VAF 50/119 reads (42%) | catalogued as rs1188927988, COSV52835878; called by muse, mutect2, varscan2
- ZNF804A | c.*2C>A | 3'UTR (SNP) | VAF 266/568 reads (47%) | catalogued as COSV100169004; called by muse, mutect2, varscan2
